Gene-level copy-number profile of tumor specimen ALCH-B1PX-TTP1-A from ALCHEMIST case ALCH-B1PX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 54.7 years (19,979 days).
Specimen ALCH-B1PX-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5db68d00-6d25-4833-a536-65dc76b20914.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1PX-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/f4e2e22f-b1f1-448a-8b7c-026acd04f12a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 543; copy number 1: 10,074; copy number 2: 36,756; copy number 3: 9,515; copy number 4: 1,960; copy number 5: 48; copy number 6: 2; copy number 7: 4; copy number 9: 2; copy number 26: 1.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:52,570,648–52,572,522, 1 gene: CRTC1P1.
- chr2:231,706,895–231,713,551, 3 genes: PTMA, U4, MIR1244-1.
- chr4:1,793,293–1,808,872, 1 gene: FGFR3.
- chr8:143,541,648–143,563,062, 4 genes: AC067930.9, AC067930.3, RN7SKP175, GSDMD.
- chr16:58,025,754–58,046,901, 1 gene: MMP15.
- chr17:39,665,349–39,670,475, 2 genes: TCAP, PNMT.
- chr17:82,078,338–82,098,294, 1 gene: FASN.
- chr19:14,472,466–14,565,980, 6 genes: PTGER1, GIPC1, SNRPGP15, DNAJB1, TECR, MIR639.
- chr19:20,416,514–20,571,095, 3 genes (within-gene range 0–1): BNIP3P22, AC008554.1, BNIP3P23.
- chr21:44,328,944–44,340,470, 4 genes: AP001062.3, CFAP410, AP001062.1, AP001062.2.
- chr22:22,644,475–22,647,903, 1 gene: GGTLC2.
- chr22:29,720,003–29,731,833, 1 gene (within-gene range 0–2): CABP7.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 57 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:194,658,376–194,664,174, 2 genes, copy number 6: Metazoa_SRP, AC006196.1.
- chr6:31,394,289–31,478,936, 7 genes, copy number 5 (within-gene range 5–6): AL645933.2, MICA, AL645933.3, Y_RNA, LINC01149, AL645933.1, HCP5.
- chr7:152,025,194–152,129,686, 4 genes, copy number 5: Metazoa_SRP, GALNT11, AC006017.1, YBX1P4.
- chr9:67,512,034–67,515,393, 1 gene, copy number 26: BX664730.1.
- chr9:67,725,690–67,726,255, 2 genes, copy number 5: FAM27B, AL627230.1.
- chr14:18,333,726–18,419,273, 4 genes, copy number 7: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr16:32,356,981–32,380,049, 2 genes, copy number 9: AC133548.1, ACTR3BP3.
- chr20:49,632,945–49,713,878, 1 gene, copy number 5: B4GALT5.
- chr21:7,744,962–8,454,792, 26 genes, copy number 5: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1.
- chr21:10,612,455–13,120,807, 8 genes, copy number 5: SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Autosomal genes at a single copy (total copy number 1): 7,746. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
